Somatic mutation profile of tumor specimen TCGA-DJ-A2Q9-01A (aliquot TCGA-DJ-A2Q9-01A-21D-A18F-08) from TCGA case TCGA-DJ-A2Q9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 65.6 years (23,951 days).
Specimen TCGA-DJ-A2Q9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0055e54f-be19-4b88-b92f-15fb881c204f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q9-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q9-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0191bbad-8849-43af-b16d-1ccaf474eafb

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 5/84 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56683107, COSV56689255; called by muse, mutect2
- ABCB7 | c.912C>A p.Y304* (on ENST00000373394 / NM_001271696.3; = p.Y305* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 4/69 reads (6%) | catalogued as COSV53722451; called by muse, mutect2
- AP3B1 | c.1379A>T p.E460V | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99672102; called by muse, mutect2
- DOCK10 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51423591; called by muse, mutect2
- FZD8 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65968285; called by muse, mutect2
- MGAT5B | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377057899, COSV56934443; called by muse, mutect2, varscan2
- MKI67 | c.4681A>G p.K1561E | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV64075956; called by muse, mutect2
- WDR49 | c.1357T>C p.C453R (on ENST00000308378 / NM_001366158.1; = p.C794R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57714782; called by muse, mutect2, varscan2
- OR2G6 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PTPRN | c.1932G>C p.R644= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV55351024; called by muse, mutect2
